Somatic mutation profile of tumor specimen HTMCP-03-06-02084-01A (aliquot HTMCP-03-06-02084-01A-01D-4427) from CGCI case HTMCP-03-06-02084, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA1; Tumor grade: G3.
Specimen HTMCP-03-06-02084-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93333a63-95f0-467b-8f0c-eb0b46c2e70c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02084-10A (Blood Derived Normal), aliquot HTMCP-03-06-02084-10A-01D-4427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f4c027f-038d-4fff-b696-cfc6a475854d

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BOD1 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as rs770230247, COSV53632560; called by muse, mutect2, varscan2
- DMXL1 | c.6166C>T p.R2056C | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs565012839; called by muse, mutect2, varscan2
- FAM47A | c.1855G>T p.G619* | Nonsense Mutation (SNP) | VAF 43/203 reads (21%) | catalogued as COSV60495212; called by muse, mutect2, varscan2
- FAT3 | c.4007G>A p.R1336H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs528757478, COSV53091298; called by muse, mutect2, varscan2
- FH | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224013, CM108468, CM149426; called by muse, mutect2, varscan2
- GRM6 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV104370795; called by muse, mutect2, varscan2
- INPP5B | c.1723G>A p.E575K (on ENST00000373023; = p.E495K on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV100886521; called by muse, mutect2, varscan2
- IRS4 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.2); catalogued as COSV64536138; called by muse, mutect2, varscan2
- MAP3K10 | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs757496454; called by muse, mutect2, varscan2
- MDC1 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV64527869; called by muse, mutect2, varscan2
- MYO16 | c.2525dup p.Q843Pfs*12 | Frame Shift Ins (INS) | VAF 23/48 reads (48%) | catalogued as rs761471964; called by mutect2, varscan2
- NRK | c.4309G>A p.D1437N | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766830131; called by muse, mutect2, varscan2
- PCDHB3 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as rs1395640142, COSV99164091; called by muse, mutect2, varscan2
- PRB3 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs748592997; called by muse, mutect2, varscan2
- PTCH1 | c.4181G>A p.R1394Q | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.04); catalogued as rs748812637, COSV59485570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF318 | c.4046G>A p.R1349Q | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs781729918; called by muse, mutect2, varscan2
- ZNF423 | c.1273C>T p.R425W (on ENST00000563137 / NM_001379286.1; = p.R417W on NM_015069.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs772823132, COSV52197113; called by mutect2, varscan2
- ANKRD36C | c.2585C>G p.T862R | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AOC1 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.7148G>A p.C2383Y | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EMILIN1 | c.2492dup p.G832Rfs*26 | Frame Shift Ins (INS) | VAF 3/19 reads (16%) | called by pindel, varscan2
- FBXO38 | c.3425C>T p.S1142F (on ENST00000340253 / NM_205836.3; = p.S1067F on NM_030793.5) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC9 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- NCKAP1 | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.3034T>C p.S1012P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTK2 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- SLC4A10 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- SNRNP200 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CFHR5 | c.313C>T p.L105= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs1327760755; called by muse, mutect2, varscan2
- COPB2 | c.1557G>A p.E519= | Silent (SNP) | VAF 16/115 reads (14%) | called by muse, mutect2, varscan2
- DOCK2 | c.735C>T p.Y245= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs374307327; called by muse, mutect2, varscan2
- DROSHA | c.2460G>A p.Q820= | Silent (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- NIPBL | c.237G>A p.L79= | Silent (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- PTPN13 | c.1257A>G p.P419= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as rs756274627; called by muse, mutect2, varscan2
- SYNE1 | c.14571G>A p.Q4857= (on ENST00000367255 / NM_182961.4; = p.Q4786= on NM_033071.3) | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as rs1327323805; called by muse, mutect2, varscan2
- UNC13B | c.4599G>A p.L1533= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- FARP2 | c.1411+165G>A | Intron (SNP) | VAF 11/50 reads (22%) | catalogued as rs780387875, COSV50870465; called by muse, mutect2, varscan2
